Somatic mutation profile of tumor specimen TCGA-B6-A2IU-01A (aliquot TCGA-B6-A2IU-01A-32D-A19T-09) from TCGA case TCGA-B6-A2IU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.7 years (22,905 days).
Specimen TCGA-B6-A2IU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56ddfd03-188f-4d9a-9070-b0c0f1c64376.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A2IU-10A (Blood Derived Normal), aliquot TCGA-B6-A2IU-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c258bdf3-8506-4252-aab1-5bcf997af80b

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Nonsense Mutation 6, RNA 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.13189G>A p.E4397K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1317620605, COSV101316459, COSV67980509; called by muse, mutect2
- APC2 | c.2489A>C p.E830A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV52022548; called by muse, varscan2
- ATP2A2 | c.1771A>G p.T591A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57876449; called by muse, mutect2, varscan2
- BRAP | c.1220A>C p.E407A | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59538741; called by muse, mutect2, varscan2
- C1GALT1 | c.891T>G p.G297= | Splice Region (SNP) | VAF 39/111 reads (35%) | catalogued as COSV56180699; called by muse, mutect2, varscan2
- CDH1 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV55731518, COSV55733848; called by muse, mutect2, varscan2
- DCAF8L1 | c.183C>A p.N61K | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.018); catalogued as rs778836758, COSV71595324, COSV71595359; called by muse, mutect2, varscan2
- DDX39A | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs754645617, COSV54393572; called by muse, mutect2, varscan2
- EMC1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.228); catalogued as COSV57674737; called by muse, mutect2, varscan2
- EMILIN2 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as rs763455124, COSV54420897; called by mutect2, varscan2
- FADS6 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs375851737; called by muse, mutect2, varscan2
- FCHO1 | c.2427G>A p.W809* | Nonsense Mutation (SNP) | VAF 7/140 reads (5%) | catalogued as COSV99406456; called by muse, mutect2
- FN3K | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318653526, COSV56183273; called by muse, mutect2, varscan2
- GUCY1A2 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV56503930; called by muse, mutect2, varscan2
- MIA3 | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs199732400; called by muse, mutect2, varscan2
- NRK | c.2126C>T p.S709L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1298451887, COSV54608126; called by muse, mutect2
- NT5C3B | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV54055922, COSV54057736; called by muse, mutect2, varscan2
- NT5DC2 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV61054561; called by muse, mutect2, varscan2
- PCDH11X | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100015835, COSV53509311; called by muse, mutect2, varscan2
- PNMA5 | c.785T>C p.F262S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV62626379; called by muse, mutect2, varscan2
- PPARGC1B | c.759C>G p.D253E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV58533653; called by muse, mutect2, varscan2
- PPP1R32 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV58545799; called by muse, mutect2, varscan2
- RHBDL3 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV52189519; called by muse, mutect2
- RILPL1 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as rs1273402938, COSV65302468; called by muse, mutect2, varscan2
- RYR3 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66810050; called by muse, mutect2, varscan2
- SYCP1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.732); catalogued as rs867423625, COSV65694161, COSV65701447; called by muse, mutect2, varscan2
- SYNE1 | c.22816G>T p.E7606* (on ENST00000367255 / NM_182961.4; = p.E7535* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV55118155; called by muse, mutect2, varscan2
- TGS1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52703585; called by muse, mutect2, varscan2
- UGGT2 | c.4118G>A p.W1373* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV65080056; called by muse, mutect2, varscan2
- UNC13A | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53196822; called by muse, mutect2, varscan2
- ZNF665 | c.982C>T p.Q328* (on ENST00000600412; = p.Q393* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as COSV67217889; called by muse, mutect2, varscan2
- ZNF75D | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV66132551, COSV66132641; called by muse, mutect2, varscan2
- ABL1 | c.3160_3169del p.S1054Wfs*12 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- ACACA | c.5633T>C p.V1878A | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- CD22 | c.879G>A p.T293= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs781077986, COSV50069427; called by muse, mutect2, varscan2
- CDKN1B | c.471C>T p.T157= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs777875072, COSV57431754; called by muse, varscan2
- CEP131 | c.360C>T p.S120= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs766135433, COSV53950433; called by muse, mutect2, varscan2
- DYRK4 | c.1371G>A p.T457= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs143171709; called by muse, varscan2
- GALK2 | c.1071C>T p.V357= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV59105695; called by muse, mutect2, varscan2
- MXRA5 | c.336C>T p.Y112= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs761442754, COSV54233569, COSV54252645; called by muse, mutect2, varscan2
- PCDHGB6 | c.1587G>A p.A529= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV53933966; called by muse, mutect2
- SIDT2 | c.1917C>T p.I639= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV54061378; called by muse, mutect2, varscan2
- ZNF438 | c.2289T>C p.P763= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV59201414; called by muse, mutect2, varscan2
- MIR519B | n.60C>T | RNA (SNP) | VAF 22/132 reads (17%) | catalogued as rs1267830083; called by muse, mutect2, varscan2
- SSX9P | n.26C>T | RNA (SNP) | VAF 68/217 reads (31%) | catalogued as rs782654039; called by muse, mutect2, varscan2
